Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABP, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABP-01A (Primary Tumor).

[page 1 of 2]
Surgery date: Surgical Pathology

ICD O-3

Carcinoma, undifferentiated NOS 802013

Site: Pancreas head C25.0

5/5/14

DIAGNOSIS:

A. Pancreas, body, margin, excision: Negative for tumor.

B. Pancreas and spleen, partial pancreatectomy and splenectomy:
Undifferentiated carcinoma with a sarcomatoid component is identified forming a solid 7.2 x 6.0 x 5.4 cm mass located in the pancreatic tail. The tumor extends beyond the pancreas involving the peripancreatic soft tissue. Angiolymphatic invasion is absent. Perineural invasion is absent. Tumor necrosis is present. All surgical resection margins are negative for tumor (minimum tumor free margin, 2.6 cm, pancreatic body margin). The patient has had no prior treatment. The adjacent non-neoplastic pancreatic parenchyma shows focal atrophy. The spleen is unremarkable. A single (1 of 22) regional lymph node is positive for metastatic carcinoma.

Immunoperoxidase studies were performed on paraffin sections of the pancreatic tail mass using antibodies directed against the following antigens: Keratin AE1/AE3, S100, CD45, SMA, desmin, CD30, ALK1. The neoplastic cells are focally positive for keratin AE1/AE3, OSCAR keratin, and smooth muscle actin while being negative for S100, desmin, CD30, ALK-1 and CD45. This immunophenotype supports above diagnosis.

Seen in consultation with

AJCC stage (with available surgical material): pT3N1 (7th edition).

Participated in interpretation:

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Pancreas, body, margin, excision: Negative for tumor.

B. Pancreas and spleen, partial pancreatectomy and splenectomy:
Poorly differentiated malignant neoplasm forming a 7.2 x 6.0 x 5.4 cm mass. The surgical margin is free by 2.6 cm. A single (1 of 22) regional lymph node is positive for metastatic carcinoma. Hold over for immunostains and classification.

Frozen section histologic interpretation performed by:

GROSS DESCRIPTION:

A. Received fresh labeled "pancreatic body margin" is a 2.6 x 1.3 x

[page 2 of 2]
0.7 cm portion of lobulated tan soft tissue without orientation.
Margin submitted en face. Grossed by

B. Received fresh labeled "distal pancreas, spleen" is a distal pancreatectomy specimen consisting of 9.2 x 7.5 x 5.5 cm portion of pancreas and 190.0 gram, 12.0 x 6.8 x 4.3 cm spleen. A 7.2 x 6.0 x 5.4 cm solid tan-yellow mass is present within the pancreas, 2.6 cm from the proximal pancreatic margin. The mass does not appear to be confined to the pancreas, grossly. Peripancreatic lymph nodes and splenic hilar lymph nodes are identified. The spleen is grossly unremarkable. Representative sections are submitted. Research tissue collected, Grossed by

BLOCK SUMMARY:

Part A: Pancreatic body margin

- 1 Pancreatic body margin 1
- 2 Pancreatic body margin 2

Part B: Distal pancreas and spleen

- 1 Pancreatic mass 1
- 2 Pancreatic mass 1
- 3 Pancreatic mass 2
- 4 Pancreatic mass 3
- 5 Pancreatic mass 4
- 6 Pancreatic mass 5
- 7 Pancreatic mass 6
- 8 Pancreatic mass 7
- 9 Spleen
- 10 Spleen
- 11 Peripancreatic LN 4(B1)
- 12 Peripancreatic LN 1(B2)
- 13 Peripancreatic LN 4(B3)
- 14 Peripancreatic LN 3(B4)
- 15 Peripancreatic LN 3(B5)
- 16 Peripancreatic LN 3(B6)
- 17 Peripancreatic LN 5(B7)
- 18 Peripancreatic LN 2(B8)
- 19 Peripancreatic LN 2(B9)

Source: NCI Genomic Data Commons file 96fabcac-9b34-4593-a66d-b7d9e2127a83 (TCGA-2J-AABP.1AB545A6-DC90-47E9-8112-DD094F6BCD02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).